Surgical pathology report (de-identified scan), TCGA case TCGA-MX-A5UJ, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site MSKCC, specimen TCGA-MX-A5UJ-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

* Addendum *

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: [REDACTED]
Account #: [REDACTED] Date of Procedure: [REDACTED]
DOB: [REDACTED] Date of Receipt: [REDACTED]
Physician: [REDACTED] Date of Report: [REDACTED]
CC: [REDACTED]
Patient Address: [REDACTED]

ICD-O-3
Adenocarcinoma, tubular
type 8211/3

Site: Stomach, gastric
antrum C16.3

gnd 3/18/13

....

Clinical Diagnosis & History:
Gastric adenocarcinoma

Specimens Submitted:
1: Distal gastrectomy (fs)
2: Portion of small bowel

DIAGNOSIS:

1. Distal gastrectomy (fs):
Part # 1

Tumor Type:

Invasive adenocarcinoma, tubular type

Lauren's Type:

Mixed [each component > 25%]

Histologic Grade:

Moderately to poorly differentiated

Tumor Involvement:

Antrum (lower third)

Tumor Size:

The length is 6.6 cm

The width is 5.7 cm

The maximum thickness is 0.6 cm

Depth of Tumor Invasion:

Tumor invades the subserosa

Preexisting Polyp (at the site of the carcinoma):
Adenomatous polyp

Vascular Invasion:

Identified

Perineural Invasion:

Identified

Multicentricity:

Not identified

Peritoneum:

Not involved

Surgical Margins:

All are free of carcinoma and dysplasia

Adjacent Mucosa:

Chronic gastritis with intestinal metaplasia

Separate Polyps:

Not identified

** Continued on next page **

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]
MRN: [REDACTED]
Account #: [REDACTED]

Accession #: [REDACTED]
Physician: [REDACTED]
Service: [REDACTED]
Date of Report: [REDACTED]

Page 2 of 4

Helicobacter Pylori:

Not identified

Lymph Nodes:

Number of nodes examined: 44

Number of lymph nodes with metastasis: 6

Tumor Staging (AJCC 7th Edition):

pT3 Tumor penetrates subserosal connective tissue without invasion
of visceral peritoneum or adjacent structure

Lymph Nodes Staging (AJCC 7th Edition):

pN2 Metastasis in 3 - 6 regional lymph nodes

2. Small bowel; resection:

- Portion of unremarkable small bowel.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh and is labeled "Distal gastrectomy". It consists of a distal portion of stomach with attached adipose tissue and omentum. The stomach measures 15.0 x 8.5 x 3.0 cm in total dimensions and has a pink tan smooth serosal surface. The attached omentum measures 15.0 x 9.3 x 3.0 cm and is grossly unremarkable. The specimen is opened to reveal gray-tan centrally ulcerated polypoid tumor. The tumor is 2.9 cm from the proximal margin and 0.5 cm from the distal margin. Representative shaved sections of proximal and distal margins were submitted for frozen section. The tumor measures 6.6 cm in length, and 5.7 cm in width. Sectioning of the tumor reveals 0.6 cm depth of invasion to the serosa. The remaining gastric mucosa shows gray-tan prominent rugae. Multiple lymph nodes are identified in the perigastric adipose tissue, measuring from 0.1 cm to 1.3 cm in greatest dimension. All identified lymph nodes are submitted. A portion of the tumor is submitted for TPS. Photographs are taken.

Summary of sections:

FSCa - representative distal and proximal margins
FSCb - representative distal and proximal margins
FSCc - representative distal and proximal margins
PM - additional representative proximal margin
DM - tumor to distal margin, perpendicular
T - tumor
U - uninvolved gastric mucosa
O - omentum

** Continued on next page **

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]
MRN: [REDACTED]
Account #: [REDACTED]

Accession #: [REDACTED]
Physician: [REDACTED]
Service: [REDACTED]
Date of Report: [REDACTED]

----- Page 3 of 4
LN - whole lymph nodes (35)
BLN - bisected lymph nodes (2)

2) The specimen is received in formalin, labeled "portion of small bowel", and consists of an unoriented portion of small bowel measuring 6.0 cm in length by 3.4 cm in average diameter. Both ends are stapled shut. The serosa is pink purple smooth and dusky. The specimen is opened to reveal gray-tan plicated mucosa, and a wall averaging 0.6 cm in thickness. Representative sections are submitted.

Summary of sections:
M - margins
U - undesignated

Summary of Sections:
Part 1: Distal gastrectomy (fs)

Block	Sect.	Site	PCs
2		BLN	4
3		DM	3
1		fsca	1
1		fsca	1
1		fscc	1
8		LN	35
1		O	1
2		PM	4
5		T	5
1		U	1

Part 2: Portion of small bowel

Block	Sect.	Site	PCs
2		M	2
1		U	2

Procedures/Addenda:

Addendum

Date Ordered: [REDACTED] Status: Signed Out
Date Complete: [REDACTED]
Date Reported: [REDACTED]

Addendum Diagnosis

Immunostain for Her2 is positive in about 30% tumor cells (3+).

** Continued on next page **

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]
MRN: [REDACTED]
Account #: [REDACTED]

Accession #: [REDACTED]
Physician: [REDACTED]
Service: [REDACTED]
Date of Report: [REDACTED]

Page 4 of 4

Immunostains for chromogranin and synaptophysin are negative in tumor cells.

*** Report Electronically Signed Out ***
Signed out by

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: Proximal and distal margins are benign
PERMANENT DIAGNOSIS: Same

** End of Report **

2/17/13
2/18/13

Source: NCI Genomic Data Commons file 1b503c11-a7b4-4020-9b22-eedc76a1dc2f (TCGA-MX-A5UJ.9C10981D-E9FB-41D4-BA40-3DE1C3F0400E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).